Gene-level copy-number profile of tumor specimen C3N-00498-02 (profiled together with C3N-00498-04) from CPTAC case C3N-00498, project CPTAC-3 (Other and ill-defined sites in lip, oral cavity and pharynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 63.3 years (23,112 days).
Specimen C3N-00498-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Oral Cavity; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2d63f861-60d8-4d9c-ba2b-57a035a56f04.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-00498-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,720 have no estimate.
https://portal.gdc.cancer.gov/files/db02f511-e542-4932-b4c8-7fe3e6c0475a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 522; copy number 1: 3,197; copy number 2: 24,472; copy number 3: 19,252; copy number 4: 8,048; copy number 5: 1,716; copy number 6: 1,560; copy number 7: 94; copy number 8: 12; copy number 12: 30.

Homozygous deletions (total copy number 0; autosomes only): 17 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,266,102–25,267,136, 1 gene (within-gene range 0–2): AL031432.2.
- chr9:21,966,929–22,128,103, 8 genes (within-gene range 0–4): CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.
- chr19:6,952,500–7,033,011, 5 genes (within-gene range 0–2): ADGRE4P, AC025278.1, AC025278.2, MBD3L2B, MBD3L5.
- chr19:20,416,514–20,571,095, 3 genes (within-gene range 0–2): BNIP3P22, AC008554.1, BNIP3P23.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,412 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–359,681, 23 genes, copy number 5 (within-gene range 2–5): DDX11L1, WASH7P, MIR6859-1, MIR1302-2HG, MIR1302-2, FAM138A, OR4G4P, OR4G11P, OR4F5, AL627309.1, AL627309.3, CICP27, AL627309.6, AL627309.7, AL627309.2, AL627309.5, RNU6-1100P, AL627309.4, FO538757.1, WASH9P, MIR6859-2, AP006222.1, AP006222.2.
- chr1:143,419,625–174,995,308, 1,094 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr1:174,849,667–186,988,981, 220 genes, copy number 5 (broad region; genes not listed).
- chr1:248,906,196–248,937,043, 3 genes, copy number 7: PGBD2, RNU6-1205P, RPL23AP25.
- chr2:41,860,155–41,894,050, 1 gene, copy number 5 (within-gene range 4–5): LINC01913.
- chr2:41,931,599–43,132,482, 25 genes, copy number 5: LINC01914, C2orf91, AC013480.1, PKDCC, EML4-AS1, EML4, COX7A2L, AC025750.2, KCNG3, VDAC1P13, RPS13P3, MTA3, Metazoa_SRP, AC025750.1, AC074375.1, RNU6-137P, OXER1, HAAO, FTOP1, CHORDC1P1, AC016735.1, LINC01819, LINC02590, RNU6-242P, LINC02580.
- chr2:197,453,423–197,786,762, 11 genes, copy number 5: COQ10B, HSPD1, HSPE1, HSPE1-MOB4, MOB4, AC020550.1, RFTN2, AC020550.2, AC011997.1, MARS2, BOLL.
- chr3:114,314,500–115,147,288, 1 gene, copy number 6 (within-gene range 4–6): ZBTB20.
- chr3:114,351,771–114,388,978, 1 gene, copy number 6 (within-gene range 4–6): ZBTB20-AS1.
- chr3:114,743,445–198,123,232, 1,461 genes, copy number 6 (broad region; genes not listed).
- chr5:180,967,189–181,006,727, 4 genes, copy number 5: AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr6:40,713,411–58,438,364, 343 genes, copy number 5–8 (broad region; genes not listed).
- chr7:52,891,837–63,088,261, 161 genes, copy number 5–7 (broad region; genes not listed).
- chr14:18,333,726–18,419,273, 4 genes, copy number 7: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr14:106,636,672–106,636,786, 1 gene, copy number 5 (within-gene range 3–5): RNA5SP389.
- chr14:106,643,142–106,652,681, 3 genes, copy number 5 (within-gene range 3–5): IGHV3-62, IGHVII-62-1, IGHV3-63.
- chr14:106,675,017–106,879,812, 26 genes, copy number 5 (within-gene range 3–5): IGHV3-66, IGHV1-67, SLC20A1P1, IGHVII-67-1, IGHVIII-67-2, IGHVIII-67-3, IGHVIII-67-4, IGHV1-68, IGHV1-69, IGHV2-70D, IGHV1-69D, IGHV2-70, IGHV3-71, IGHV3-72, IGHV3-73, IGHV3-74, IGHVII-74-1, IGHV3-75, IGHV3-76, IGHVIII-76-1, MIR5195, IGHV5-78, IGHVII-78-1, IGHV3-79, IGHV7-81, IGHVIII-82.
- chr17:21,614,487–22,706,703, 30 genes, copy number 12: AC233702.1, AC233702.4, AC233702.9, KCNJ18, ABBA01006766.1, NCOR1P2, UBBP4, FTLP13, LINC02002, AC138761.1, AC138761.2, FAM27E5, AC087575.1, FLJ36000, AC132825.3, AC132825.4, MTCYBP13, MTRNR2L1, AC132825.2, MTND1P15, MTND2P13, AC132825.1, NMTRS-TGA3-1, MTATP6P3, MTCO3P13, AC131055.2, AC131055.1, AC131274.3, AC131274.1, AC131274.2.

Autosomal genes at a single copy (total copy number 1): 856. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
